Somatic mutation profile of tumor specimen 0DPX3R from CCDI case PBCDYM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,122 days).
Specimen 0DPX3R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7561fca3-c722-498f-a06d-222abf9d4345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPX38 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e61b033-b189-41d4-99c8-7a7502c6a43d

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPSF1 | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 77/537 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs782075836, COSV58232625; called by muse, mutect2, varscan2
- RABL6 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 166/337 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs376411410, COSV99051472; called by muse, mutect2, varscan2
- SLC25A28 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 216/540 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs754677257, COSV65125242; called by muse, mutect2, varscan2
- FOXO3 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKI67 | c.6317C>T p.P2106L | Missense Mutation (SNP) | VAF 375/829 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.4); called by muse, mutect2, varscan2
